Surgical pathology report (de-identified scan), TCGA case TCGA-CM-6675, project TCGA-COAD (Colon Adenocarcinoma), tissue source site MSKCC, specimen TCGA-CM-6675-01A (Primary Tumor).

[page 1 of 4]
[REDACTED]

[REDACTED]

[REDACTED]

SURGICAL PATHOLOGY REPORT

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

....

Clinical Diagnosis & History:
RLQ tenderness, CT scan revealed mass at hepatic flexure at colon and mass at segment 7. Colonoscopy revealed mass of colon. Biopsy shown increased lymphoplasmacytic infiltration at lamina propria. Carcinoma of hepatic flexure with liver mass.

Specimens Submitted:
1: Lymph node, base of superior mesentery artery, excision [REDACTED]
2: Lymph node, middle colic, excision [REDACTED]
3: Colon, right, hemi-colectomy

DIAGNOSIS:
1. Lymph node, base of superior mesentery artery, excision [REDACTED]
-Metastatic moderately differentiated adenocarcinoma in one of two lymph nodes (1/2).

2. Lymph node, middle colic, excision [REDACTED]
-One benign lymph node (0/1).

3. Colon, right, hemi-colectomy:
Tumor Type:
Adenocarcinoma
Histologic Grade:
Moderately differentiated
Tumor Location:
Cecum
Tumor Size:
Length is 8 cm
Width is 6 cm
Maximal thickness is 1.8 cm
Tumor Budding:
Extensive
Increased Tumor Infiltrating Lymphocytes:
Absent
Precursor Lesions:
Not identified
Deepest Tumor Invasion:
Subserosal adipose tissue and/or mesenteric fat
Gross Tumor Perforation:

** Continued on next page **

[page 2 of 4]
Not identified
Lymphovascular Invasion:
Identified
Large Venous Invasion:
Not Identified
Perineural Invasion:
Identified
Surgical Margins:
Free of tumor
Polyps/Mucosa Dysplasia (away from the carcinoma):
Not Identified
Non-Neoplastic Bowel:
Unremarkable
Appendix:
Not identified.
Lymph Nodes:
Number with metastasis: 12
Total number examined: 72
Tumor deposits in pericorectal soft tissue:
Identified
Identified; number:1
Tumor Staging (AJCC 7th Edition):
pT3 (Tumor invades through the muscularis propria into
pericorectal tissues)
Lymph Node Stage (AJCC 7th Edition):
N2b (Metastasis in seven or more regional lymph nodes)

Note: Results of immunohistochemical staining for DNA mismatch repair
proteins are as follows:
MLH1: Staining present in tumor
MSH2: Staining present in tumor
MSH6: Staining present in tumor
PMS2: Staining present in tumor
Conclusion:Immunohistochemical staining for the tested DNA mismatch repair
proteins is retained in the tumor.

Some of the immunohistochemistry and ISH tests were developed and their
performance characteristics were determined by the Department of Pathology.
They have not been cleared or approved by the US Food and Drug
Administration. The FDA has determined that such clearance or approval is
not necessary. These tests are used for clinical purposes. They should not
be regarded as investigational or for research. This laboratory is certified
under the Clinical Laboratory Improvement Amendments of [REDACTED] (CLIA ' [REDACTED] as
qualified to perform high complexity clinical laboratory testing.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF
THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED
THIS REPORT.

[REDACTED]

** Continued on next page **

[page 3 of 4]
Gross Description:

1. The specimen is received fresh for frozen section labeled "base of superior mesenteric artery lymph node" are two lymph nodes each measure 0.5 cm greatest dimension. The lymph nodes are entirely submitted for frozen section.

Summary of sections:

FSC-frozen section control

2. The specimen is received fresh for frozen section labeled "middle colic lymph node" is a 1.0 cm lymph node. The lymph node is bisected and entirely submit of the frozen section.

Summary of sections:

FSC-frozen section control

3). The specimen is received fresh, labeled "Right hemi-colectomy" and consists of a segment of terminal ileum, cecum and ascending colon. The terminal ileum measures 14 cm in length and 3 cm in circumference at the proximal resected margin. The remaining colon measures 40 in length with a circumference of 6 cm at the distal resected margin. The appendix is not present. The intestinal serosa is pink tan and smooth. Focally hemorrhagic lobulated yellow tan adipose tissue spans the length of the specimen measuring up to 5 cm in thickness. The specimen is opened to reveal a circumferential mass lesion measuring 6 cm in length and 8 cm in width. The mass is located in the cecum, 23 cm from the proximal margin and 15 cm from the distal margin. Sectioning shows that the tumor invades the fat. The depth of invasion is 1.8 cm grossly. Right underneath the mass is a 4 x 2.5 x 2 cm conglomerate of five nodules with yellow/white cut surface (distance from tumor surface to the deepest portion of the conglomerate is 4.8 cm). The remaining mucosa is unremarkable. The specimen is submitted for lymph node dissection. The attached adipose tissue is thoroughly examined and all identified lymph nodes are submitted. Representative sections of the specimen are submitted for permanent sections and for TPS.

Summary of sections:

P - proximal margin shave

D - distal margin shave

T - tumor

RS -representative sections

LN - lymph nodes

BLN - bisected lymph nodes

C - conglomerate of 5 nodes, representative section

** Continued on next page **

[page 4 of 4]
Summary of Sections:

Part 1: Lymph node, base of superior mesentery artery, excision ()

Block	Sect.	Site	PCs
1		FSC	1

Part 2: Lymph node, middle colic, excision ()

Block	Sect.	Site	PCs
1		fsc	1

Part 3: Colon, right, hemi-colectomy

Block	Sect.	Site	PCs
5		BLN	5
1		C	1
1		D	1
10		LN	20
1		P	1
1		RS	1
6		T	6

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. Frozen Section Diagnosis: Base of superior mesentery artery lymph node

() Positive for metastatic adenocarcinoma. ()

Permanent Diagnosis: SAME

2. Frozen Section Diagnosis: Middle colic lymph node () Benign. ()

Permanent Diagnosis: SAME

** End of Report **

Source: NCI Genomic Data Commons file 4a7e45ad-6542-44ce-97db-6a54733ad707 (TCGA-CM-6675.5DBFD78D-0F01-401C-8E64-934DB33A89DA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).